Gene-level copy-number profile of tumor specimen ALCH-AEU9-TTP1-A from ALCHEMIST case ALCH-AEU9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 50.8 years (18,557 days).
Specimen ALCH-AEU9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 09a7dc5c-3828-4bfd-84da-3b79db3ffbb1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEU9-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/978cadfb-10e4-4945-b5af-992e578ca54c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 488; copy number 1: 424; copy number 2: 135; copy number 3: 15,485; copy number 4: 17,040; copy number 5: 9,810; copy number 6: 11,807; copy number 7: 2,459; copy number 8: 339; copy number 9: 493; copy number 10: 168; copy number 11: 68; copy number 12: 38; copy number 14: 4; copy number 15: 20; copy number 17: 5; copy number 19: 10; copy number 20: 32; copy number 28: 15; copy number 35: 15; copy number 36: 60; copy number 73: 1.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr17:22,266,395–22,706,703, 21 genes: AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3, AC132825.4, MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC131055.2, AC131055.1, AC131274.3, AC131274.1, AC131274.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 929 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:70,242,588–73,620,631, 44 genes, copy number 10: CSN3, CABS1, SMR3A, SMR3B, OPRPN, MUC7, AMTN, AMBN, ENAM, AC009570.2, JCHAIN, UTP3, RNU6-520P, RNU6-784P, AC009570.1, RUFY3, GRSF1, RNU6-891P, MOB1B, DCK, SLC4A4, AC096713.1, LDHAL6EP, GC, RNA5SP163, AC068721.1, NPFFR2, ADAMTS3, AC095056.1, HNRNPA1P67, RNU4ATAC9P, RNU6ATAC5P, COX18, ANKRD17, HMGA1P2, AC053527.2, AC053527.1, AC108157.1, ALB, AFP, AFM, LINC02499, AC074250.1, RASSF6.
- chr4:75,641,849–75,724,589, 1 gene, copy number 11 (within-gene range 3–11): G3BP2.
- chr4:75,724,577–75,941,013, 5 genes, copy number 11 (within-gene range 8–11): USO1, AC110615.1, RNU2-16P, PPEF2, NAAA.
- chr4:94,117,792–101,348,883, 81 genes, copy number 10–15 (broad region; genes not listed).
- chr5:58,198–473,098, 19 genes, copy number 10: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080.
- chr5:473,236–480,884, 1 gene, copy number 10 (within-gene range 7–10): SLC9A3-AS1.
- chr5:18,886,622–21,341,375, 17 genes, copy number 9–12: UBE2V1P12, AC025768.1, AC114981.1, Metazoa_SRP, AC106744.1, AC106744.2, RPL32P14, HSPD1P15, CDH18, AC093303.1, AC094103.1, CDH18-AS1, LINC02146, LINC02241, AC138938.1, AC140172.1, AC093274.1.
- chr5:50,396,192–54,310,582, 53 genes, copy number 10: EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2, RNA5SP182, KATNBL1P4, AC091903.1, LINC02118, RPS17P11, MFSD4BP1, AC022126.1, PELO, ITGA1, AC022133.2, B3GNTL1P1, AC022133.1, AC025180.1, ITGA2, AC008966.3, AC008966.2, MOCS2, AC008966.1, AC026477.1, AC108114.1, FST, NDUFS4, LINC02105, ASS1P9, AC025175.1, ARL15, AC025175.2, RNU6-272P, MIR581, RN7SL801P, AC016601.1, AC008873.1.
- chr7:12,726,152–13,751,920, 1 gene, copy number 9 (within-gene range 3–9): AC011287.1.
- chr7:13,339,201–43,566,001, 487 genes, copy number 9–12 (within-gene range 7–12) (broad region; genes not listed).
- chr7:47,740,202–47,948,466, 1 gene, copy number 12 (within-gene range 6–12): PKD1L1.
- chr7:47,795,291–48,108,736, 6 genes, copy number 12: C7orf69, AC069282.1, HUS1, SUN3, C7orf57, UPP1.
- chr8:34,874,159–43,544,057, 190 genes, copy number 11–73 (broad region; genes not listed).
- chr14:18,333,726–18,419,273, 4 genes, copy number 14: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr17:68,793,549–69,903,000, 19 genes, copy number 9: AC011591.1, ABCA8, ABCA9-AS1, ABCA9, ABCA6, SEC24AP1, MIR4524B, MIR4524A, ABCA10, PRO1804, AC005495.1, ABCA5, SNRPGP4, AC115085.1, MAP2K6, AC015920.1, AC002546.1, LINC01483, AC002545.1.

Autosomal genes at a single copy (total copy number 1): 375. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
